Somatic mutation profile of tumor specimen TARGET-30-PATCKU-01A (aliquot TARGET-30-PATCKU-01A-01D) from TARGET case TARGET-30-PATCKU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.6 years (2,038 days).
Specimen TARGET-30-PATCKU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8a623f-403a-4424-90fb-badcd7871950.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATCKU-10A (Blood Derived Normal), aliquot TARGET-30-PATCKU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085f4af1-e260-45d6-8238-e385a6929cd1

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP400 | c.7724T>C p.V2575A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.944); catalogued as COSV57766305; called by muse, mutect2, varscan2
- NF2 | c.*1556C>A | 3'UTR (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.*466C>A | 3'UTR (SNP) | VAF 88/317 reads (28%) | catalogued as COSV61622452; called by muse, mutect2, varscan2
